TCGA case TCGA-QQ-A5VB — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f94362d-368f-4570-b8c1-70fc4b1f5e35

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 1,478 days (4.0 years).

Diagnoses (5)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.9; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues, NOS; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,654 days); Year of diagnosis: 1994; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Contiguous organ invaded: Colon; Sites of involvement: Common or Superficial Femoral Vein / Small intestine / Colon, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 18.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.4; Tumor length measurement: 13.2; Tumor width measurement: 9.
2. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 54.1 years (19,765 days); Days to diagnosis: 111 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 11.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 11; Tumor width measurement: 1.4.
   Pathology details: Measurement type: Radiologic; Tumor burden: 17.
3. Recurrence of diagnosis 1 (Leiomyosarcoma, NOS), site: Pelvis, NOS. Age at diagnosis: 54.1 years (19,768 days); Days to diagnosis: 114 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 10.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 8; Tumor length measurement: 10.5; Tumor width measurement: 8.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Descending colon. Age at diagnosis: 57.9 years (21,130 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 0.4.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.2; Tumor length measurement: 0.4; Tumor width measurement: 0.3.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Intestinal tract, NOS. Age at diagnosis: 57.9 years (21,130 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 80.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 16.2; Tumor length measurement: 80.5; Tumor width measurement: 24.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (6 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Day 111 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 111 days; Discontiguous lesion count: 1.
- Day 114 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 114 days; Discontiguous lesion count: 1.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Descending colon; Days to progression: 1,476 days (4.0 years); Discontiguous lesion count: 1.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intestinal tract, NOS; Days to progression: 1,476 days (4.0 years); Discontiguous lesion count: 2.
- Days to follow up: 1,478 days (4.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A5VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-QQ-A5VB-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A5VB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A5VB-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 730 mg.
  Slide TCGA-QQ-A5VB-11B-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: Common or superficial femoral vein; Margin status: Positive; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Colon and Small Bowel; Contiguous organ invaded: Yes; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Synovial sarcoma: Mpnst nf1 genetic testing indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Groin.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 9.0.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment: Pharmaceutical treatment ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,478 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,478 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 111 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A5VB-01A-11D-A36I-01): tumor purity 0.45, ploidy 3.26, whole-genome doublings 2.
